Somatic mutation profile of tumor specimen ALCH-B1VW-TTR1-A (aliquot ALCH-B1VW-TTR1-A-1-0-D-A88E-36) from ALCHEMIST case ALCH-B1VW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,847 days).
Specimen ALCH-B1VW-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ede6021-87ca-4b3c-9d84-e4adc3e6082a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VW-NB1-A (Blood Derived Normal), aliquot ALCH-B1VW-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/473fdd7a-04ca-48d9-96e8-4dab6a93e389

The open-access MAF lists 256 somatic variants for this specimen: 180 protein-altering or splice-affecting, 49 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 49, Nonsense Mutation 11, Intron 11, 5'UTR 5, 3'UTR 5, RNA 3, Splice Site 3, Splice Region 3, Frame Shift Del 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 46/351 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS17 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 25/289 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs138284004; called by muse, mutect2
- ADGRG4 | c.7063G>T p.G2355C | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV54954635; called by muse, mutect2, varscan2
- ADGRL3 | c.2717G>T p.R906L (on ENST00000506720 / NM_001322402.2; = p.R838L on NM_015236.6) | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV101547490; called by muse, mutect2
- APOBEC1 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 38/229 reads (17%) | catalogued as COSV57549077; called by muse, mutect2, varscan2
- ARMCX6 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1351235915; called by muse, mutect2
- ATP6V0D2 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150345297; called by muse, mutect2
- ATXN7L1 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV69308243; called by muse, mutect2
- CACNA1E | c.3147C>A p.S1049R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV62414869; called by muse, varscan2
- CHRM2 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57769127, COSV57775493; called by muse, mutect2
- CLVS1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs148453129, COSV57972301; called by muse, mutect2
- CMPK2 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 42/445 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1431381398, COSV56774713; called by muse, mutect2
- CNTN6 | c.183G>T p.R61S | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs374282825; called by muse, mutect2
- CRACD | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99948295; called by muse, mutect2
- CSMD1 | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs760230512, COSV68248557; called by muse, mutect2
- CSMD3 | c.9698G>T p.C3233F (on ENST00000297405 / NM_001363185.1; = p.C3064F on NM_052900.3) | Missense Mutation (SNP) | VAF 29/451 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853170; called by muse, mutect2
- CSTA | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1328491943; called by muse, mutect2
- DCAF12L2 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1473145155; called by muse, mutect2
- DNAH10 | c.1872G>T p.K624N (on ENST00000409039; = p.K563N on NM_207437.3) | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV68991931, COSV69002833; called by muse, mutect2
- DNMT3B | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749197342, COSV52415308; called by muse, mutect2, varscan2
- DSCAM | c.1425G>T p.Q475H | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); catalogued as COSV68023556; called by muse, mutect2
- EIF2B4 | c.1070G>T p.R357L (on ENST00000347454 / NM_001034116.2; = p.R356L on NM_015636.3) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as CM023068; called by muse, mutect2
- F8 | c.4600C>T p.P1534S | Missense Mutation (SNP) | VAF 20/507 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV64269877; called by muse, mutect2
- FGF23 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 21/472 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1287649555; called by muse, mutect2
- GALNT14 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139825623; called by muse, mutect2, varscan2
- HECTD4 | c.8671C>T p.P2891S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as rs1043230620; called by muse, mutect2
- HGF | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 48/690 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as COSV55948011; called by muse, mutect2
- KCND2 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.533); catalogued as COSV58578418; called by muse, mutect2
- KLHL6 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV58069562; called by muse, mutect2
- KRT8 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 25/350 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV53176520; called by muse, mutect2
- KRTAP6-2 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 26/271 reads (10%) | PolyPhen benign (0.003); catalogued as COSV100588896; called by muse, mutect2
- LCE2D | c.90del p.K31Nfs*43 | Frame Shift Del (DEL) | VAF 21/132 reads (16%) | catalogued as rs762629502, COSV64229250; called by mutect2, varscan2
- LCP2 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50458080; called by muse, mutect2
- LILRA1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs919874018, COSV52182057, COSV52185670; called by muse, mutect2
- MAN1A2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100741028; called by muse, mutect2
- MED23 | c.3317A>G p.H1106R | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs745402762; called by muse, mutect2
- MRE11 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs890702534; called by muse, mutect2
- NELL1 | c.1069C>A p.R357= | Splice Region (SNP) | VAF 29/262 reads (11%) | catalogued as COSV54255758; called by muse, mutect2, varscan2
- NSMCE3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as rs761816470; called by muse, mutect2
- NYX | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as CM139645, COSV61181742; called by muse, varscan2
- OR4C6 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV58602640; called by muse, mutect2
- OVCH1 | c.2851G>T p.G951C | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs756609612; called by muse, mutect2
- PCDH15 | c.4882C>T p.P1628S (on ENST00000644397 / NM_001354429.2; = p.P1570S on NM_001142771.2) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64724931; called by muse, mutect2, varscan2
- PCNX2 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV50848177; called by muse, mutect2, varscan2
- PKP1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs1472136920; called by muse, mutect2
- PODN | c.1567G>T p.A523S (on ENST00000395871; = p.A475S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.063); catalogued as rs1180644482; called by muse, mutect2, varscan2
- RHCE | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs374399829, CM096722, COSV53799323, COSV99603783; called by muse, mutect2, varscan2
- RYR2 | c.14720C>A p.T4907N | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63663048; called by muse, mutect2, varscan2
- SAGE1 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.307); catalogued as rs781964038; called by muse, mutect2
- SETD1A | c.3809C>G p.A1270G | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV52684674; called by muse, mutect2
- SP140L | c.1665G>T p.M555I | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs763863593, COSV54742467; called by muse, mutect2
- SPINT1 | c.1217G>A p.R406H (on ENST00000344051 / NM_181642.3; = p.R390H on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1358454566, COSV59801253; called by muse, mutect2
- TDO2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as rs200566767, COSV72483916; called by muse, mutect2
- TECRL | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV67085362; called by muse, mutect2
- TJP1 | c.3244G>T p.D1082Y | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs960821749; called by muse, mutect2
- TM4SF20 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58818483; called by muse, mutect2
- TMEM41B | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV55154745; called by muse, mutect2
- TNN | c.2551G>C p.V851L | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV99511961; called by muse, mutect2
- TRPS1 | c.1139A>G p.N380S (on ENST00000220888 / NM_001330599.2; = p.N393S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1305445021; called by muse, mutect2, varscan2
- TTC37 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 27/594 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769976381; called by muse, mutect2
- USPL1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs141598959; called by muse, mutect2
- VWF | c.3944G>T p.R1315L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs61749396, CM070319, CM070321, CM163415; ClinVar: not provided; called by mutect2, varscan2
- ZNF256 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99990900; called by muse, mutect2
- ZNF735 | c.117T>A p.N39K | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752865023; called by muse, mutect2
- A2M | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AARS1 | c.1762C>G p.Q588E | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ABCC12 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.076); called by muse, mutect2
- ABCC5 | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- AC244197.3 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ACACA | c.5680-2A>C p.X1894_splice | Splice Site (SNP) | VAF 17/306 reads (6%) | called by muse, mutect2
- ACOD1 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ACTN2 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 50/294 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2
- ADCY9 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, mutect2
- AHDC1 | c.3398A>T p.D1133V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- ANKRD30B | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.096); called by muse, mutect2
- ATP12A | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- BNIP5 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.134); called by muse, mutect2
- C1QL4 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.029); called by muse, mutect2
- CACNA2D1 | c.2540T>A p.V847E (on ENST00000356253 / NM_001366867.1; = p.V835E on NM_000722.4) | Missense Mutation (SNP) | VAF 20/603 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2
- CAD | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2
- CCDC168 | c.13302G>T p.L4434F | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CCNA1 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CCT8L2 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2
- CD163 | c.744T>A p.C248* | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- CKM | c.192A>T p.P64= | Splice Region (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- CNTNAP2 | c.1373G>A p.W458* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- CPA4 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- CPN1 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2
- CPSF3 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CR1L | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CYP7A1 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DAB2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DGKI | c.2689G>C p.G897R | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.933); called by muse, mutect2
- DNALI1 | c.436_437delinsT p.R146Sfs*12 (on ENST00000296218; = p.R124Sfs*12 on NM_003462.5) | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by pindel, varscan2*
- DSE | c.1432A>T p.T478S | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DSG4 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- DYRK3 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.153); called by muse, mutect2
- EPB41L2 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FANCM | c.2898G>T p.E966D | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2
- FBXW10 | c.885A>T p.R295S | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2
- FCHO2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- FCRL2 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2
- GABRA2 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.917); called by muse, mutect2
- GABRG2 | c.847G>T p.V283F (on ENST00000361925 / NM_001375343.1; = p.V243F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/606 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2
- GPC3 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2B | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2
- GTDC1 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- GUCY1A2 | c.1256T>A p.I419N | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- HBD | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 54/644 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HDX | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- HMCN1 | c.16132G>C p.V5378L | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- IGSF5 | c.527G>T p.W176L | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IKBIP | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- JAM2 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 29/593 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2
- KIAA1549 | c.4615G>T p.A1539S | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA1755 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- KIF2B | c.1141A>T p.N381Y | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- LAMA2 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 43/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA3 | c.8152G>T p.G2718* (on ENST00000313654 / NM_198129.4; = p.G1109* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- LEPR | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2
- LNP1 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.048); called by muse, mutect2
- LRRC4C | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- LRRC63 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- MAGEB6B | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- MAGEH1 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MAP1B | c.4159T>A p.S1387T | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- MOGAT3 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MPO | c.1204+5G>T | Splice Region (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- NEK5 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRP12 | c.3142G>C p.A1048P | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); called by muse, mutect2
- NLRP13 | c.2991C>G p.C997W | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- NOX5 | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2
- NPY5R | c.1184A>T p.D395V | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by muse, mutect2
- NRCAM | c.2589G>T p.E863D (on ENST00000379028 / NM_001371124.1; = p.E847D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.108); called by muse, mutect2
- OGA | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 24/410 reads (6%) | called by muse, mutect2
- OR2C3 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2L2 | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR4C6 | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4N5 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5J2 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- PA2G4 | c.30A>T p.Q10H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- PDE3B | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PIAS2 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.338); called by muse, mutect2
- PLCB3 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POU3F4 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2
- PSG11 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PYHIN1 | c.943A>T p.N315Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2
- RELCH | c.3537G>T p.M1179I | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- RLIM | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- RSPH9 | c.308T>A p.F103Y | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2
- RYR1 | c.7837T>A p.Y2613N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.133); called by muse, mutect2
- RYR3 | c.5653A>T p.N1885Y | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2
- SAMD9 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA6D | c.2861C>G p.P954R (on ENST00000316364 / NM_153618.2; = p.P892R on NM_020858.2) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- SLC22A2 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SLC4A11 | c.1639A>T p.S547C | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2
- SLC9A2 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMCHD1 | c.1229G>T p.S410I | Missense Mutation (SNP) | VAF 41/521 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2
- SSX2IP | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2
- TAF1L | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TBX15 | c.1388A>T p.E463V (on ENST00000369429 / NM_001330677.2; = p.E357V on NM_152380.3) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2
- TIAM1 | c.2143G>T p.V715L | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- TMEM196 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.801); called by muse, mutect2
- TRO | c.2103C>G p.S701R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- TUB | c.90+1G>T p.X30_splice (on ENST00000299506 / NM_177972.3; = p.X85_splice on NM_003320.4) | Splice Site (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- USP15 | c.2544G>T p.L848F (on ENST00000280377 / NM_001351159.2; = p.L819F on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP20 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- USP54 | c.4200G>T p.E1400D | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2
- VCP | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 45/444 reads (10%) | called by muse, mutect2, varscan2
- WASHC2A | c.292-1G>T p.X98_splice | Splice Site (SNP) | VAF 18/517 reads (3%) | called by muse, mutect2
- ZFHX4 | c.6752C>T p.P2251L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF236 | c.5229A>G p.I1743M | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF292 | c.7367C>G p.S2456* | Nonsense Mutation (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- ZNF449 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF527 | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF676 | c.1205G>T p.C402F (on ENST00000650058; = p.C370F on NM_001001411.3) | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF711 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.222); called by muse, mutect2
- ZNF804A | c.3599C>A p.P1200H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACTL7A | c.351C>T p.F117= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs533456952; called by muse, mutect2
- ADAMTS19 | c.3117C>T p.G1039= | Silent (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- ADAMTSL3 | c.3835C>T p.L1279= | Silent (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- ADH1B | c.498C>A p.P166= | Silent (SNP) | VAF 33/642 reads (5%) | called by muse, mutect2
- ANKMY1 | c.807A>G p.E269= | Silent (SNP) | VAF 16/374 reads (4%) | called by muse, mutect2
- APEX2 | c.252C>A p.T84= | Silent (SNP) | VAF 9/44 reads (20%) | called by mutect2, varscan2
- APLNR | c.675C>A p.A225= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- ATP8B4 | c.1728C>G p.V576= | Silent (SNP) | VAF 18/404 reads (4%) | catalogued as COSV52711318; called by muse, mutect2
- C3 | c.4428A>T p.A1476= | Silent (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- CACNA1E | c.792C>A p.P264= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV62386758, COSV62405104; called by muse, mutect2
- CCDC152 | c.258G>A p.L86= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- DCAF12L2 | c.252C>G p.P84= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100758636, COSV63581468; called by muse, mutect2
- DPYSL3 | c.1677C>T p.P559= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as rs933380784; called by muse, mutect2
- ELMO1 | c.1608A>G p.L536= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- FAT1 | c.3771G>T p.R1257= | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- FER | c.711A>T p.T237= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- FRMPD2 | c.741C>A p.P247= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV100563807; called by muse, mutect2
- GCN1 | c.3660A>T p.G1220= | Silent (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
- HMCN1 | c.1407A>T p.T469= | Silent (SNP) | VAF 52/616 reads (8%) | called by muse, mutect2
- KBTBD11 | c.456C>T p.R152= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- KCNQ5 | c.864A>G p.E288= | Silent (SNP) | VAF 24/321 reads (7%) | called by muse, mutect2
- KCNT2 | c.3024C>A p.P1008= | Silent (SNP) | VAF 53/369 reads (14%) | called by muse, mutect2, varscan2
- KIAA1549L | c.3333T>A p.T1111= (on ENST00000321505; = p.T1408= on NM_012194.3) | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- KLF9 | c.714G>A p.K238= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- LAIR2 | c.54C>A p.T18= | Silent (SNP) | VAF 13/326 reads (4%) | catalogued as COSV56622952; called by muse, mutect2
- LOXHD1 | c.2859G>A p.E953= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- LRBA | c.8262T>C p.C2754= | Silent (SNP) | VAF 28/398 reads (7%) | catalogued as rs774130942; called by muse, mutect2
- MAGEB6B | c.651G>A p.L217= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- MROH2A | c.2436C>T p.V812= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- MRPL46 | c.714A>T p.L238= | Silent (SNP) | VAF 32/575 reads (6%) | called by muse, mutect2
- NRAP | c.396T>A p.A132= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- OLFML1 | c.711C>A p.I237= | Silent (SNP) | VAF 23/243 reads (9%) | catalogued as rs1014931578, COSV55081156; called by muse, mutect2, varscan2
- OR11L1 | c.597C>T p.I199= | Silent (SNP) | VAF 21/310 reads (7%) | called by muse, mutect2
- OR51F2 | c.663C>A p.I221= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1458195303, COSV59065915; called by muse, mutect2, varscan2
- OR6V1 | c.255C>A p.V85= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- OR9A4 | c.864C>T p.F288= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV71885719; called by muse, mutect2, varscan2
- PEX5L | c.306A>G p.T102= | Silent (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- PIEZO2 | c.1803C>A p.L601= | Silent (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2, varscan2
- PIK3C2G | c.4146G>A p.V1382= (on ENST00000676171; = p.V1341= on NM_004570.5) | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as rs1319864585; called by muse, mutect2
- PIK3R1 | c.591C>T p.V197= | Silent (SNP) | VAF 36/547 reads (7%) | called by muse, mutect2
- PLXNB3 | c.207C>A p.G69= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV62795457; called by muse, mutect2
- PTBP2 | c.108G>T p.P36= (on ENST00000426398 / NM_001300986.2; = p.P28= on NM_021190.4) | Silent (SNP) | VAF 20/268 reads (7%) | catalogued as COSV64623364; called by muse, mutect2
- RHBDD1 | c.75C>T p.N25= | Silent (SNP) | VAF 16/328 reads (5%) | called by muse, mutect2
- SAT1 | c.180G>T p.P60= | Silent (SNP) | VAF 19/154 reads (12%) | catalogued as COSV63380715; called by muse, mutect2, varscan2
- SEMA4A | c.1221G>T p.L407= | Silent (SNP) | VAF 15/213 reads (7%) | catalogued as rs552696817; called by muse, mutect2
- SPATA31D1 | c.1686C>A p.P562= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- TMPRSS2 | c.1131G>A p.Q377= | Silent (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- UGT2B11 | c.1452C>A p.T484= | Silent (SNP) | VAF 40/604 reads (7%) | called by muse, mutect2
- USH2A | c.3603T>C p.H1201= | Silent (SNP) | VAF 65/525 reads (12%) | called by muse, mutect2, varscan2
- AC002428.1 | chr5:135922406 G>T | 5'Flank (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- AL353804.7 | chrX:73851206 C>G | 3'Flank (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- C8orf44-SGK3 | c.-312C>G | 5'UTR (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
- CALCR | c.52-3316G>A | Intron (SNP) | VAF 36/303 reads (12%) | called by muse, mutect2, varscan2
- CD55 | c.-24G>T | 5'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- CLU | c.*118G>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- DHRS7B | c.-39C>T | 5'UTR (SNP) | VAF 20/264 reads (8%) | catalogued as rs764853081; called by muse, mutect2
- DIP2C | c.85+27408G>T | Intron (SNP) | VAF 13/304 reads (4%) | called by muse, mutect2
- F7 | c.*11C>A | 3'UTR (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- GABRA6 | c.39-30G>T | Intron (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- GABRB3 | c.461+5265C>A | Intron (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- INTS4 | c.1515-22C>T | Intron (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- LSS | c.*135T>A | 3'UTR (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- MMGT1 | c.-266C>T | 5'UTR (SNP) | VAF 12/262 reads (5%) | catalogued as rs868965600; called by muse, mutect2
- NBPF22P | n.274C>A | RNA (SNP) | VAF 8/286 reads (3%) | called by muse, mutect2
- PRPF31 | c.1276-35G>A | Intron (SNP) | VAF 8/100 reads (8%) | catalogued as rs1276223516, COSV100319827; called by muse, mutect2
- PTPRQ | c.19+1203G>T | Intron (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- RBM5 | c.483+9A>G | Intron (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- RNF170 | c.-8+36C>T | Intron (SNP) | VAF 10/138 reads (7%) | catalogued as rs1175877968, COSV53568883; called by muse, mutect2
- SLC5A1 | chr22:32039597 G>T | 5'Flank (SNP) | VAF 26/393 reads (7%) | called by muse, mutect2
- TMPRSS11B | c.-29C>T | 5'UTR (SNP) | VAF 30/329 reads (9%) | called by muse, mutect2
- TTN | c.34264+591C>A | Intron (SNP) | VAF 23/628 reads (4%) | catalogued as COSV100636156; called by muse, mutect2
- UBE2DNL | n.532G>T | RNA (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- UBE2DNL | n.533G>T | RNA (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- UGT1A6 | c.862-23525G>C | Intron (SNP) | VAF 15/122 reads (12%) | catalogued as rs199947040; called by muse, mutect2, varscan2
- VCX3A | c.*6C>A | 3'UTR (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- VCX3A | c.*5C>A | 3'UTR (SNP) | VAF 16/272 reads (6%) | catalogued as COSV66910774; called by muse, mutect2
